Somatic mutation profile of tumor specimen C3N-00577-04 (aliquot CPT0069180009) from CPTAC case C3N-00577, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.7 years (26,555 days).
Specimen C3N-00577-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1f80206-e977-4c4b-b3ff-5876722765d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00577-71 (Blood Derived Normal), aliquot CPT0069270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca99012e-7569-4165-84d5-8823717bd924

The open-access MAF lists 53 somatic variants for this specimen: 29 protein-altering or splice-affecting, 18 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 18, Intron 4, Frame Shift Del 2, Splice Site 1, 5'Flank 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF4 | c.1859C>A p.S620Y | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1208947343; called by muse, mutect2
- AQP9 | c.480C>G p.N160K | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV54967546; called by muse, mutect2, varscan2
- DR1 | c.516T>A p.D172E | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV64725888; called by muse, mutect2, varscan2
- GDF10 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs782581244; called by muse, mutect2
- MYO3B | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs556789877; called by muse, mutect2, varscan2
- AJM1 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2
- CCDC166 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.117); called by muse, mutect2
- CDIP1 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.559); called by muse, mutect2
- COL22A1 | c.443del p.L148Rfs*81 | Frame Shift Del (DEL) | VAF 25/174 reads (14%) | called by mutect2, pindel, varscan2
- CRHR2 | c.619T>A p.C207S | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); called by muse, mutect2
- DRD4 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 62/489 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- GOLGA8J | c.115A>T p.N39Y | Missense Mutation (SNP) | VAF 27/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GPD1 | c.17T>A p.V6D | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LYST | c.2530A>G p.I844V | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- OTOP2 | c.458T>A p.F153Y | Missense Mutation (SNP) | VAF 22/395 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PBRM1 | c.4680+2T>C p.X1560_splice (on ENST00000296302 / NM_001366071.2; = p.X1453_splice on NM_018313.5) | Splice Site (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- RABGGTA | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- RDH13 | c.386G>T p.R129L (on ENST00000415061 / NM_001145971.2; = p.R58L on NM_138412.4) | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RELN | c.8608C>T p.Q2870* | Nonsense Mutation (SNP) | VAF 18/198 reads (9%) | called by muse, mutect2
- SHOX | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 56/605 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.193); called by muse, mutect2
- SLC22A7 | c.943A>G p.S315G (on ENST00000372585 / NM_153320.2; = p.S313G on NM_006672.3) | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); called by muse, mutect2
- SNAP91 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- TBX5 | c.212del p.G71Afs*4 | Frame Shift Del (DEL) | VAF 48/512 reads (9%) | called by mutect2, pindel
- THRA | c.1112A>T p.E371V | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TIAM1 | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- TLN1 | c.4118T>C p.V1373A | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.186); called by muse, mutect2
- TRIM26 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ZFR | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 39/337 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF470 | c.1189T>A p.F397I | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- ANKRD39 | c.264T>G p.A88= | Silent (SNP) | VAF 82/439 reads (19%) | called by muse, mutect2, varscan2
- CLUH | c.2169A>G p.S723= (on ENST00000435359; = p.S762= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/186 reads (10%) | called by muse, mutect2, varscan2
- CUX1 | c.57A>G p.V19= (on ENST00000292535 / NM_181552.4; = p.V30= on NM_001913.5) | Silent (SNP) | VAF 17/187 reads (9%) | catalogued as rs1278377019; called by muse, mutect2
- KIR3DL3 | c.57C>T p.P19= | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- KMT2E | c.4833C>T p.P1611= | Silent (SNP) | VAF 28/322 reads (9%) | catalogued as rs1243172763; called by muse, mutect2
- KRTAP4-9 | c.585C>G p.V195= | Silent (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- LRAT | c.615T>C p.S205= | Silent (SNP) | VAF 17/197 reads (9%) | called by muse, mutect2
- OIT3 | c.312T>C p.A104= | Silent (SNP) | VAF 24/326 reads (7%) | called by muse, mutect2
- OR9K2 | c.463C>T p.L155= (on ENST00000305377; = p.L133= on NM_001005243.1) | Silent (SNP) | VAF 21/273 reads (8%) | called by muse, mutect2
- RGS20 | c.174G>A p.P58= | Silent (SNP) | VAF 40/237 reads (17%) | catalogued as COSV52020210; called by muse, mutect2, varscan2
- SETD1A | c.723C>A p.T241= | Silent (SNP) | VAF 42/467 reads (9%) | called by muse, mutect2
- SIGLECL1 | c.180C>T p.T60= | Silent (SNP) | VAF 36/361 reads (10%) | called by muse, mutect2, varscan2
- SIN3A | c.300G>A p.Q100= | Silent (SNP) | VAF 16/361 reads (4%) | catalogued as COSV64582507; called by muse, mutect2
- SLC6A12 | c.780T>C p.L260= | Silent (SNP) | VAF 22/377 reads (6%) | called by muse, mutect2
- TIMM44 | c.438G>A p.K146= | Silent (SNP) | VAF 49/529 reads (9%) | catalogued as COSV54494255; called by muse, mutect2
- TTC34 | c.2356C>T p.L786= | Silent (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- USP34 | c.7800C>A p.A2600= | Silent (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- WDR81 | c.1098G>C p.L366= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- COPZ2 | c.112-258C>T | Intron (SNP) | VAF 9/119 reads (8%) | called by muse, mutect2
- GLRX | chr5:95823891 C>A | 5'Flank (SNP) | VAF 32/288 reads (11%) | catalogued as rs751794723; called by muse, mutect2, varscan2
- LINC00602 | n.1069G>C | RNA (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- MADCAM1 | c.667+1225C>T | Intron (SNP) | VAF 22/229 reads (10%) | called by muse, mutect2
- PELP1 | c.1068+53C>T | Intron (SNP) | VAF 56/425 reads (13%) | called by muse, mutect2, varscan2
- PIWIL1 | c.2469+17G>C | Intron (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
